Surgical pathology report (de-identified scan), TCGA case TCGA-L3-A4E7, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Gundersen Lutheran Health System, specimen TCGA-L3-A4E7-01A (Primary Tumor).

[page 1 of 2]
Patient:

Med. Record No.:
Date of Birth:
Submitted by:
Report also to:

Age:
Sex: M

Pathology #:
Date of Procedure:
Date Received:

Pathology Report

DIAGNOSIS:

ICD-0-3

carcinoma, squamous cell, NOS
8070/3

SPECIMEN

Specimen type: Lobectomy
Tumor site: Right lower lobe

Site: Lung, lower lobe C34.3

W
9/27/12

TUMOR

Histologic type: Squamous cell carcinoma
Histologic grade: Poorly differentiated (G3 of 4)
Tumor size: 3.1cm
Tumor focality: Unifocal
Direct extension of tumor: No invasion of visceral pleura or adjacent structures
Tumor-associated atelectasis/obstructive pneumonitis: Absent
Lymphovascular space invasion: Absent
Additional findings: None
Comment: An elastic stain supports lack of visceral pleural invasion.

MARGINS

All margins negative for carcinoma
Distance to nearest margin: 3cm
Nearest margin: Bronchial margin

LYMPH NODES

All sampled lymph nodes are benign
Number of nodes evaluated: 11

STAGING (AJCC)

Primary Tumor: pT2a
Lymph Nodes: pN0

W
9/12/12

CLINICAL INFORMATION:
Right lung nodule.

SPECIMEN(S) RECEIVED:

Pathology Report

[page 2 of 2]
Patient: [REDACTED]

Right lower lobe -

research specimen

GROSS DESCRIPTION:

Received fresh is a 150.6 gram lobe of lung measuring 18.5 x 15.0 x 4.5 cm in greatest dimensions. The pleural surface is tan-red with moderate anthracotic stippling. Located approximately 3 cm from the bronchial margin is a 3.1 x 2.2 x 1.9 cm granular tan-gray subpleural mass. The mass has a cavitated center containing purulent material. The mass extends to, but does not penetrate through, the pleura. Subsequent sectioning of the lung reveals a spongy pink parenchyma with no additional masses. There are multiple 0.2 cm to 1.1 x 1.1 x 0.4 cm peribronchial lymph nodes. Two sections are submitted for frozen section evaluation: A1 - bronchial margin; A2 - tumor. A portion of the tumor is obtained for the frozen section remnants are submitted for permanent sections. Additional sections: A3 - tumor with overlying pleura (inked black); A4 - additional tumor; A5 - representative non-tumorous lung; A6-A9 - multiple individual peribronchial lymph nodes, intact.

FROZEN SECTION DIAGNOSIS: Non-small cell lung carcinoma, negative bronchial margin.

notified of the frozen section diagnosis at

Slides were microscopically examined by the pathologist

Evaluation performed by

Source: NCI Genomic Data Commons file a15c4508-6ccb-45cc-ac2c-308a73c8653e (TCGA-L3-A4E7.83686883-C3FA-43DA-9C85-F0A6319B7F57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).